Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A40P, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A40P-01A (Primary Tumor).

Site Is (Circle):		

7/14/12

Spec. Taken

=====

INTERPRETATION AND DIAGNOSIS:

1) THYROID (TOTAL THYROIDECTOMY):
SPECIMEN TYPE:
TOTAL THYROIDECTOMY

TUMOR SITE:
RIGHT LOBE

HISTOLOGIC TYPE:
PAPILLARY CARCINOMA, FOLLICULAR VARIANT

Per TSS on 7/12/12, follicular variant = 99%
ju

TUMOR SIZE:
GREATEST DIMENSION 3.2 CM

FOCALITY:
UNIFOCAI

ICD-O-3
carcinoma, papillary, follicular variant
8340/3

LYMPH NODES:
1 LYMPH NODE IS NEGATIVE FOR TUMOR

Site: thyroid, Nos

EXTENT OF INVASION (Edition AJCC):
PRIMARY TUMOR:
pT2: TUMOR >2 CM BUT <4 CM, LIMITED TO THYROID

C73.9

7-18-12 RD

REGIONAL LYMPH NODES:
pNO: NO REGIONAL LYMPH NODE METASTASIS

DISTANT METASTASIS:
pMx: CANNOT BE ASSESSED

MARGINS:
MARGINS ARE UNINVOLVED.
DISTANCE OF INVASIVE CARCINOMA FROM NEAREST MARGIN: 1 MM.
SPECIFY MARGIN: ANTERIOR & POSTERIOR

VENOUS/LYMPHATIC INVASION:
ABSENT

ADDITIONAL PATHOLOGIC FINDINGS:
PARATHYROID GLAND, RIGHT UPPER LOBE
ONE LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

NOTE: This case was shown at the

Source: NCI Genomic Data Commons file 56d37373-5c7f-4503-8e07-90a134164f26 (TCGA-ET-A40P.BC87B4BA-1694-4472-9616-D1C83671B416.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).